Gene-level copy-number profile of tumor specimen TCGA-46-3769-01A from TCGA case TCGA-46-3769, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; Age at diagnosis: 57.3 years (20,941 days).
Specimen TCGA-46-3769-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.aeb3f438-7a30-45bf-87ac-acd2e0845bdc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-46-3769-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 823 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/75a173fb-5226-42b8-a65a-89716f93f905

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 307; copy number 1: 219; copy number 2: 12,711; copy number 3: 19,303; copy number 4: 15,343; copy number 5: 5,374; copy number 6: 3,485; copy number 7: 1,534; copy number 8: 508; copy number 9: 675; copy number 10: 125; copy number 11: 100; copy number 12: 11; copy number 14: 61; copy number 18: 1; copy number 21: 30; copy number 23: 11; copy number 24: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-46-3769-01A-01D-0978-01): tumor purity 0.47, ploidy 3.65, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 307 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–4,994,972, 64 genes (within-gene range 0–2) (broad region; genes not listed).
- chr8:7,418,991–11,267,865, 139 genes (within-gene range 0–2) (broad region; genes not listed).
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,929,457–32,573,184, 94 genes (within-gene range 0–3) (broad region; genes not listed).
- chr11:80,527,960–80,762,826, 3 genes: RNU6-544P, ARL6IP1P3, LINC02720.
- chr12:17,383,352–17,400,914, 2 genes: PSMC1P8, TIMM17BP1.
- chr20:14,884,250–15,022,958, 4 genes (within-gene range 0–3): MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,058 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,318,114–8,344,167, 1 gene, copy number 7 (within-gene range 5–7): SLC45A1.
- chr1:8,352,397–9,369,532, 28 genes, copy number 7 (within-gene range 5–7): RERE, RERE-AS1, AL096855.1, AL096855.2, RPL7P11, RPL7P7, Y_RNA, AL357552.1, AL357552.2, RPL23AP19, ENO1, MIR6728, ENO1-AS1, RNU6-304P, HMGN2P17, AL139415.1, AL139415.2, CA6, RN7SL451P, SLC2A7, SLC2A5, AL158048.1, GPR157, MIR34AHG, MIR34A, LNCTAM34A, H6PD, SPSB1.
- chr1:90,835,660–99,842,761, 150 genes, copy number 7 (broad region; genes not listed).
- chr1:236,664,141–248,919,946, 280 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr2:63,883,249–64,252,859, 7 genes, copy number 7: AC114748.1, VPS54, AC012368.2, PELI1, AC012368.1, LINC00309, AC012368.3.
- chr2:185,547,135–185,833,290, 5 genes, copy number 7 (within-gene range 5–7): ELF2P4, FSIP2-AS1, U8, FSIP2-AS2, FSIP2.
- chr3:11,745–1,987,470, 20 genes, copy number 7: LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32, AC090044.1, AC087430.1, RN7SL120P, CNTN6, CRB3P1, RPL23AP38, RPL23AP39, RPL21P17, AC018814.1.
- chr3:19,389,185–20,186,206, 11 genes, copy number 7 (within-gene range 3–7): AC061958.1, EFHB, HSPA8P18, RAB5A, PP2D1, RNU4-85P, SAP18P3, RPL39P18, KAT2B, MIR3135A, SGO1.
- chr4:51,843,000–55,636,698, 76 genes, copy number 11–21 (broad region; genes not listed).
- chr6:16,761,138–27,109,980, 213 genes, copy number 7–9 (broad region; genes not listed).
- chr6:32,098,176–33,804,003, 110 genes, copy number 7 (broad region; genes not listed).
- chr6:46,492,052–53,794,904, 130 genes, copy number 8–9 (broad region; genes not listed).
- chr6:54,307,859–57,961,501, 44 genes, copy number 8 (within-gene range 3–8): TINAG, TINAG-AS1, CLNS1AP1, RPL10P10, RPSAP44, KRASP1, RNU6-1023P, AL512363.1, FAM83B, AL049555.1, HCRTR2, GFRAL, HMGCLL1, AL590290.1, BMP5, NPM1P36, COL21A1, DHFRP6, AL031779.1, RCC2P7, DST, DST-AS1, RPL17P26, RNU6-626P, BEND6, OSTCP6, FTH1P15, MRPL30P1, KIAA1586, ZNF451, ZNF451-AS1, BAG2, RAB23, PRIM2, MIR548U, FO680682.1, AL021368.3, AL021368.5, AL021368.1, AL021368.2, GUSBP4, AL021368.4, POM121L14P, LINC00680.
- chr6:57,967,687–58,073,134, 2 genes, copy number 8: GAPDHP15, AL390237.1.
- chr7:70,972–24,981,634, 398 genes, copy number 7–11 (broad region; genes not listed).
- chr7:54,721,724–56,617,957, 72 genes, copy number 14–23 (broad region; genes not listed).
- chr10:71,396,920–81,137,335, 242 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr11:66,040,765–80,327,911, 479 genes, copy number 7 (broad region; genes not listed).
- chr11:127,657,568–128,241,441, 4 genes, copy number 11–24: AP003532.1, DNAJB6P1, LINC02725, LINC02098.
- chr12:10,111,738–11,196,996, 54 genes, copy number 8: HNRNPABP1, CLEC7A, OLR1, TMEM52B, GABARAPL1, GABARAPL1-AS1, KLRD1, LINC02617, LINC02598, KLRK1-AS1, KLRK1, KLRC4-KLRK1, KLRC4, AC068775.1, KLRC3, KLRC2, KLRC1, EIF2S3B, SLC25A39P2, LINC02446, KLRA1P, MAGOHB, STYK1, YBX3, LINC02366, HSPE1P12, TAS2R7, TAS2R8, TAS2R9, PRH1, TAS2R10, AC006518.1, PRR4, AC018630.4, AC006518.2, TAS2R13, PRH2, TAS2R14, TAS2R15P, TAS2R50, TAS2R20, TAS2R19, TAS2R31, TAS2R63P, TAS2R46, TAS2R64P, TAS2R43, AC018630.1, TAS2R30, AC134349.2, AC134349.1, SMIM10L1, TAS2R42, AC244131.1.
- chr12:27,105,151–27,502,185, 6 genes, copy number 8 (within-gene range 5–8): AC092747.1, AC092747.2, STK38L, ARNTL2, ARNTL2-AS1, SMCO2.
- chr12:28,133,249–28,581,511, 1 gene, copy number 8 (within-gene range 5–8): CCDC91.
- chr12:28,505,394–34,249,958, 122 genes, copy number 8 (broad region; genes not listed).
- chr12:53,210,567–55,312,757, 108 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr18:23,506,184–46,920,160, 287 genes, copy number 7–12 (within-gene range 4–12) (broad region; genes not listed).
- chr18:47,808,957–50,825,402, 73 genes, copy number 9 (broad region; genes not listed).
- chr20:25,919,499–33,443,763, 135 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 217. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
